Somatic mutation profile of tumor specimen TARGET-10-PARDSP-09A (aliquot TARGET-10-PARDSP-09A-01D) from TARGET case TARGET-10-PARDSP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,165 days).
Specimen TARGET-10-PARDSP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbd45cbf-098f-41cb-a6f9-b6759c156b04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDSP-10A (Blood Derived Normal), aliquot TARGET-10-PARDSP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0781cc64-3718-4241-831c-1e3fbe55ff1b

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 3, Splice Region 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP39 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs150289481; called by muse, mutect2, varscan2
- CHD7 | c.5768G>A p.S1923N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as CD112412; called by muse, mutect2, varscan2
- COL15A1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1384259809; called by muse, mutect2, varscan2
- DSCAML1 | c.5128C>T p.P1710S (on ENST00000321322; = p.P1650S on NM_020693.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1474179275; called by muse, mutect2, varscan2
- GRID1 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354128891, COSV60057999; called by muse, mutect2, varscan2
- IGHV5-51 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 89/143 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs573975337; called by muse, mutect2, varscan2
- KIRREL3 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765790781; called by muse, mutect2, varscan2
- KRT38 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs564375775; called by muse, mutect2, varscan2
- TTN | c.66985C>T p.R22329W (on ENST00000591111; = p.R14905W on NM_003319.4) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | PolyPhen probably damaging (0.999); catalogued as rs748041610, COSV59932620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD4 | c.2891A>T p.E964V (on ENST00000357008 / NM_001363606.2; = p.E977V on NM_001273.5) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTNAP2 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- EP300 | c.5350C>T p.Q1784* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- KCTD1 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLKB1 | c.1488T>A p.T496= | Splice Region (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- TRDD2 | chr14:22439013 TACCACAC>G | Missense Mutation (DEL) | VAF 44/87 reads (51%) | called by pindel, varscan2*
- ENPP1 | c.627G>A p.T209= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs774561788, COSV62932487; called by muse, mutect2, varscan2
- FAM47C | c.123G>A p.P41= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs782696018, COSV63725468, COSV63731070; called by muse, mutect2, varscan2
- FAT2 | c.5865A>G p.K1955= | Silent (SNP) | VAF 40/115 reads (35%) | called by muse, mutect2, varscan2
- PNPLA4 | c.351C>T p.N117= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs370490518; called by muse, mutect2, varscan2
- ST7 | c.1578A>G p.K526= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- FARP1 | c.171+31355A>T | Intron (SNP) | VAF 9/34 reads (26%) | called by muse, varscan2
- HSH2D | c.126-1045C>T | Intron (SNP) | VAF 18/33 reads (55%) | catalogued as rs8101408; called by muse, mutect2, varscan2
- PILRB | c.*45C>T | 3'UTR (SNP) | VAF 15/47 reads (32%) | catalogued as rs749299066, COSV60333153; called by muse, mutect2, varscan2
- TTC28 | c.5120-64A>G | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
